Somatic mutation profile of tumor specimen TCGA-B0-5088-01A (aliquot TCGA-B0-5088-01A-01D-1462-08) from TCGA case TCGA-B0-5088, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.9 years (19,677 days).
Specimen TCGA-B0-5088-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2dd16de-4a1c-4f76-80cc-d0f08995a808.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5088-11A (Solid Tissue Normal), aliquot TCGA-B0-5088-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a653322b-ade2-4618-b454-bbf4c06e5262

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Intron 2, In Frame Del 2, Nonsense Mutation 2, 5'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKNAD1 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV62199893; called by muse, mutect2, varscan2
- ARIH1 | c.684T>C p.T228= | Splice Region (SNP) | VAF 19/97 reads (20%) | catalogued as rs768369523, COSV65912060; called by muse, mutect2, varscan2
- ATP1A3 | c.1977C>G p.N659K (on ENST00000545399 / NM_001256214.2; = p.N646K on NM_152296.5) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV100131802, COSV57488759; called by muse, mutect2, varscan2
- ATXN7 | c.1177del p.T393Pfs*6 | Frame Shift Del (DEL) | VAF 74/287 reads (26%) | catalogued as COSV55748635; called by mutect2, pindel, varscan2
- BAP1 | c.29G>C p.S10T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234612, COSV56234931, COSV56236530; called by muse, varscan2
- CCNB2 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as rs1433361474, COSV55596052; called by muse, mutect2, varscan2
- CHL1 | c.825C>A p.N275K (on ENST00000397491 / NM_001253387.1; = p.N291K on NM_006614.4) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs772480546, COSV56596824; called by muse, mutect2
- CNTNAP1 | c.3422G>C p.G1141A | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52851762, COSV99227056; called by muse, mutect2, varscan2
- COL1A1 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM930142, COSV56806698; called by muse, mutect2, varscan2
- CRISP3 | c.614+1G>A p.X205_splice (on ENST00000371159 / NM_001368123.1; = p.X187_splice on NM_006061.4) | Splice Site (SNP) | VAF 14/212 reads (7%) | catalogued as rs762333204, COSV53819771, COSV53821819; called by muse, mutect2
- EEF1AKNMT | c.1159C>G p.Q387E (on ENST00000361735 / NM_015935.5; = p.Q301E on NM_014955.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV62283325; called by muse, mutect2, varscan2
- EEFSEC | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54621659, COSV54627821; called by muse, mutect2, varscan2
- EXPH5 | c.4042G>C p.A1348P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56204169; called by muse, mutect2, varscan2
- F2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs189436668; called by muse, mutect2
- FAM83D | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV54156355, COSV54158010, COSV99465009; called by muse, mutect2, varscan2
- FLNC | c.6590G>A p.R2197Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.208); catalogued as rs760535041, COSV100368545, COSV57958312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFRAL | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs1562052554, COSV61232337; called by muse, mutect2, varscan2
- IGF2BP2 | c.965A>T p.E322V | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60487471; called by muse, mutect2, varscan2
- KCNV2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746257061, COSV66055647; called by muse, mutect2
- KIAA1841 | c.1653G>C p.Q551H | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54376074; called by muse, mutect2
- KLK13 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs200569857, COSV50067242; called by muse, mutect2, varscan2
- LYST | c.8979T>G p.F2993L | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV67708851; called by muse, mutect2
- MAPK4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309062743, COSV68542652; called by muse, mutect2, varscan2
- MEGF9 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs201374644, COSV64236275; called by muse, mutect2, varscan2
- MLIP | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 82/459 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV51432130; called by muse, mutect2, varscan2
- MYOM3 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV58396003; called by muse, mutect2, varscan2
- NAGK | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs560847516, COSV54903964; called by muse, mutect2
- NAV3 | c.4630+1G>T p.X1544_splice | Splice Site (SNP) | VAF 9/136 reads (7%) | catalogued as COSV57090334; called by muse, mutect2
- NOS1 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57615313; called by muse, mutect2, varscan2
- NRIP1 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 20/216 reads (9%) | catalogued as COSV59658372; called by muse, mutect2
- PAPSS2 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63263928; called by muse, mutect2, varscan2
- REV3L | c.4844C>G p.S1615C | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as COSV62620566; called by muse, mutect2
- RNF115 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs782787353, COSV100991569, COSV65165016; called by muse, mutect2
- SCML1 | c.599G>T p.G200V (on ENST00000380041 / NM_001037540.3; = p.G173V on NM_006746.6) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as COSV66240851; called by muse, mutect2, varscan2
- SIN3A | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64583644; called by muse, mutect2, varscan2
- SLC22A16 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57931254; called by muse, mutect2, varscan2
- SLC52A2 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57352411; called by muse, mutect2, varscan2
- SLITRK3 | c.1301T>C p.L434S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53849778; called by muse, mutect2
- SPOUT1 | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771013793, COSV63509483; called by muse, mutect2, varscan2
- STAG3 | c.3644T>C p.L1215S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV57931916; called by muse, mutect2
- TBC1D15 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV59847484; called by muse, mutect2, varscan2
- TM9SF3 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64457792; called by muse, mutect2
- VHL | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040270, CM093522, COSV56544329, COSV56550485, COSV56556920; called by muse, mutect2, varscan2
- VIL1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs750796385, COSV50288679; called by mutect2, varscan2
- VWA8 | c.2101A>C p.N701H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV55699282; called by muse, mutect2, varscan2
- YME1L1 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as rs1210962432, COSV58760235; called by muse, mutect2, varscan2
- ZNF711 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.515); catalogued as rs1427911141, COSV52156083; called by muse, mutect2, varscan2
- NSMCE4A | c.386_388del p.E129del | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- PANK2 | c.579dup p.T194Hfs*36 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PRKAG2 | c.1173_1178del p.I391_G393delinsM | In Frame Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- PSMB4 | c.374_375insT p.H126Tfs*4 | Frame Shift Ins (INS) | VAF 55/213 reads (26%) | called by mutect2, pindel, varscan2
- TMEM63B | c.1275_1282del p.R426Hfs*74 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- VPS37B | c.784_785del p.P262Ifs*71 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ABCC9 | c.4326C>T p.V1442= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV53976369; called by muse, mutect2
- CACNG5 | c.255G>A p.L85= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV50056772; called by muse, mutect2, varscan2
- CCNT2 | c.1386A>G p.E462= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV51474311; called by muse, mutect2, varscan2
- CTBP2 | c.685C>T p.L229= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs749510602, COSV58335104; called by muse, mutect2, varscan2
- DACT1 | c.1755G>A p.K585= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV60021718; called by muse, mutect2, varscan2
- DST | c.16302A>G p.E5434= (on ENST00000361203 / NM_001374722.1; = p.E3022= on NM_015548.5) | Silent (SNP) | VAF 77/294 reads (26%) | catalogued as COSV55023132; called by muse, mutect2, varscan2
- EEFSEC | c.1329G>T p.R443= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV54627837; called by muse, mutect2, varscan2
- GNL2 | c.114C>T p.I38= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV66080922; called by muse, mutect2, varscan2
- KLHL41 | c.1332A>T p.S444= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV52930731; called by muse, mutect2, varscan2
- LRP1B | c.2076A>C p.S692= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV67239777; called by muse, mutect2
- OSBPL6 | c.2262C>G p.T754= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV51921673; called by muse, mutect2, varscan2
- PCDHA11 | c.81G>A p.G27= | Silent (SNP) | VAF 64/195 reads (33%) | catalogued as rs1554162580, COSV56483361; called by muse, mutect2, varscan2
- PPP1R16A | c.93C>T p.A31= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52953647; called by muse, mutect2, varscan2
- SLIT2 | c.747G>A p.E249= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as COSV56578480, COSV56596137; called by muse, mutect2
- SYNJ1 | c.846T>A p.V282= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV59150856; called by muse, mutect2
- ZNF789 | c.1077T>C p.H359= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV58874686; called by muse, mutect2, varscan2
- ABCA1 | c.720+2584G>C | Intron (SNP) | VAF 15/109 reads (14%) | catalogued as COSV101036690; called by muse, mutect2, varscan2
- MAD1L1 | c.472-1531C>G | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56233462, COSV99765458; called by muse, mutect2, varscan2
- MIR1297 | n.12A>T | RNA (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853906 T>G | 5'Flank (SNP) | VAF 25/182 reads (14%) | catalogued as rs1172346168; called by muse, mutect2, varscan2
